Somatic mutation profile of cancer-model specimen HCM-BROD-0220-C15-85B (2D Modified Conditionally Reprogrammed Cells, passage 10; aliquot HCM-BROD-0220-C15-85B-01D-A79C-36), derived from the metastatic tumor of HCMI case HCM-BROD-0220-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: GX; Age at diagnosis: 60.2 years (21,985 days).
Specimen HCM-BROD-0220-C15-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 795f6022-a8c0-4d6e-9754-39bd7b081947.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0220-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0220-C15-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6524be92-7dbf-48f2-8c67-ec917b68802a

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Frame Shift Del 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC099489.1 | c.878T>A p.L293Q | Missense Mutation (SNP) | VAF 211/427 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753045135; called by muse, mutect2, varscan2
- ADGRE5 | c.318C>G p.F106L | Missense Mutation (SNP) | VAF 229/457 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.915); catalogued as COSV99662693; called by muse, mutect2, varscan2
- CHRFAM7A | c.353G>A p.R118K | Missense Mutation (SNP) | VAF 180/393 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs775546722; called by muse, mutect2, varscan2
- SUSD2 | c.986C>T p.T329M | Missense Mutation (SNP) | VAF 185/403 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs756754262, COSV64204863; called by muse, mutect2, varscan2
- TJP3 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 186/388 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749562116; called by muse, varscan2
- ARMH4 | c.1435C>A p.Q479K | Missense Mutation (SNP) | VAF 134/285 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- BIRC6 | c.9801del p.Q3268Sfs*3 | Frame Shift Del (DEL) | VAF 193/473 reads (41%) | called by mutect2, pindel, varscan2
- CDC42BPA | c.2107del p.E703Nfs*13 | Frame Shift Del (DEL) | VAF 82/206 reads (40%) | called by mutect2, pindel, varscan2
- DHX32 | c.641_647del p.I214Tfs*6 | Frame Shift Del (DEL) | VAF 134/307 reads (44%) | called by mutect2, pindel, varscan2
- LCLAT1 | c.956A>G p.Y319C | Missense Mutation (SNP) | VAF 238/488 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAT10 | c.584A>C p.K195T | Missense Mutation (SNP) | VAF 160/318 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- TTC36 | c.457_458del p.G153Qfs*34 | Frame Shift Del (DEL) | VAF 454/1144 reads (40%) | called by mutect2, pindel, varscan2
- VPS13B | c.3992_4001del p.P1331Lfs*2 | Frame Shift Del (DEL) | VAF 121/318 reads (38%) | called by mutect2, pindel, varscan2
- FITM1 | c.621C>T p.Y207= | Silent (SNP) | VAF 320/655 reads (49%) | called by muse, mutect2, varscan2
- HSP90AB1 | c.1185C>T p.L395= | Silent (SNP) | VAF 186/404 reads (46%) | called by muse, mutect2, varscan2
